Gene-level copy-number profile of tumor specimen TCGA-24-1550-01A from TCGA case TCGA-24-1550, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.4 years (18,049 days).
Specimen TCGA-24-1550-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.308919de-3238-4f7a-a68c-97bcae3252a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1550-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d5ba3a1-5370-40ff-92b1-c5eea8e1c376

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 19,734; copy number 2: 32,561; copy number 3: 5,724; copy number 4: 1,695; copy number 5: 44; copy number 6: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1550-01A-01D-0497-01): tumor purity 0.77, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–409,417, 8 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr10:75,397,830–75,431,588, 5 genes: ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,743,755, 5 genes: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr15:43,870,761–44,195,271, 1 gene (within-gene range 0–1): FRMD5.
- chr15:43,989,061–44,064,313, 2 genes: ACTBP7, GAPDHP55.
- chr20:10,317,889–10,387,806, 4 genes: AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2.
- chr20:16,177,933–16,573,448, 3 genes (within-gene range 0–1): AL161941.1, PPIAP17, KIF16B.
- chr22:33,704,786–33,750,843, 4 genes: SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:148,695,994–149,503,394, 29 genes, copy number 5: RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5.
- chr3:149,525,631–149,525,726, 1 gene, copy number 5: RNU6-1098P.
- chr3:193,957,372–194,322,871, 14 genes, copy number 6: LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1.
- chr8:77,399,072–79,314,951, 14 genes, copy number 5: AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1.

Autosomal genes at a single copy (total copy number 1): 19,734. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
